CCDI case PBBIRM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/69885f54-3e3f-43a8-93f5-dcca187d0f7d

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 7.7 years (2,806 days).

Biospecimens (3 samples)
- Sample 0D9CLB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9CLC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9CLN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
